Gene-level copy-number profile of tumor specimen TCGA-85-7697-01A from TCGA case TCGA-85-7697, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 49.1 years (17,921 days).
Specimen TCGA-85-7697-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1343a3ff-d66b-47e7-ac55-e9dd1caa3dcd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-7697-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/33a815b8-aa1e-4710-8709-a8fab529eabf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 25,092; copy number 2: 30,708; copy number 3: 3,021; copy number 4: 323; copy number 5: 622; copy number 8: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-7697-01A-11D-2121-01): tumor purity 0.36, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:82,773,319–82,990,298, 4 genes: AC099506.1, AC099506.3, RN7SL134P, AC125793.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 666 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:166,569,693–198,222,513, 622 genes, copy number 5 (broad region; genes not listed).
- chr16:69,187,129–69,309,052, 1 gene, copy number 8 (within-gene range 4–8): SNTB2.
- chr16:69,299,682–70,372,582, 43 genes, copy number 8 (within-gene range 1–8): AC026464.4, VPS4A, COG8, PDF, AC026464.6, AC026464.3, AC026464.1, NIP7, TMED6, TERF2, CYB5B, AC026464.5, AC026464.2, NFAT5, MIR1538, AC009032.1, AC012321.1, NQO1, AC092115.2, AC092115.3, NOB1, AC092115.1, WWP2, SNORA62, MIR140, CLEC18A, AC026468.1, PDXDC2P-NPIPB14P, NPIPB14P, PDXDC2P, MIR1972-2, AC009022.1, PDPR, AC009060.1, CLEC18C, AC009060.2, SMG1P7, EXOSC6, AARS1, RN7SL279P, DDX19B, AC012184.2, AC012184.3.

Autosomal genes at a single copy (total copy number 1): 22,709. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
